Somatic mutation profile of tumor specimen TCGA-25-1328-01A (aliquot TCGA-25-1328-01A-01W-0492-08) from TCGA case TCGA-25-1328, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 38.1 years (13,911 days).
Specimen TCGA-25-1328-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 422e3c20-1910-46b6-8d44-c88d62fb1f78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-1328-10A (Blood Derived Normal), aliquot TCGA-25-1328-10A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08ffa62d-18e9-4f94-a26f-7772f0bf5bb7

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, Frame Shift Ins 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.12416T>A p.I4139K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV67988236; called by muse, mutect2, varscan2
- CDH23 | c.2705G>A p.G902D | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.969); catalogued as COSV99821860; called by muse, varscan2
- CEACAM7 | c.539G>A p.W180* | Nonsense Mutation (SNP) | VAF 111/352 reads (32%) | catalogued as rs781944676, COSV50073325; called by muse, mutect2, varscan2
- CEP19 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56360165; called by muse, mutect2, varscan2
- CLCNKB | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs201608930, COSV65160976; called by muse, mutect2, varscan2
- DNAH11 | c.10774T>C p.Y3592H | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs777007114, COSV60962492; called by muse, mutect2, varscan2
- DTNA | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 94/284 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV52009543; called by muse, mutect2, varscan2
- HAS3 | c.1393G>A p.G465S | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT tolerated (0.45); PolyPhen probably damaging (1); catalogued as COSV99544488; called by muse, mutect2
- KLB | c.1769C>G p.A590G | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.038); catalogued as COSV99962250; called by muse, mutect2
- MAST4 | c.905C>T p.T302M (on ENST00000403625 / NM_001164664.2; = p.T113M on NM_015183.3) | Missense Mutation (SNP) | VAF 19/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370889678; called by muse, mutect2
- MDN1 | c.13877C>A p.T4626N | Missense Mutation (SNP) | VAF 13/342 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV101021507; called by muse, mutect2
- PCDHB10 | c.1040T>A p.L347Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as COSV53380598; called by muse, varscan2
- SPATA31D1 | c.2469G>T p.Q823H | Missense Mutation (SNP) | VAF 11/302 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV100782847; called by muse, mutect2
- SYNGR2 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 13/221 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99857308; called by muse, mutect2
- TAS2R16 | c.872G>A p.C291Y | Missense Mutation (SNP) | VAF 209/655 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); catalogued as COSV50797473; called by muse, mutect2, varscan2
- TBC1D25 | c.398T>C p.L133P | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV65123968; called by muse, mutect2, varscan2
- TEX264 | c.215C>A p.P72H | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100392658; called by muse, mutect2
- ZNF503 | c.1638_1639insA p.G547Rfs*176 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- ACO2 | c.1869C>T p.N623= | Silent (SNP) | VAF 70/415 reads (17%) | catalogued as COSV99347523; called by muse, varscan2
- ACO2 | c.1908C>T p.V636= | Silent (SNP) | VAF 56/318 reads (18%) | catalogued as COSV99347525; called by muse, varscan2
- ATP1A3 | c.2490C>T p.A830= (on ENST00000545399 / NM_001256214.2; = p.A817= on NM_152296.5) | Silent (SNP) | VAF 12/362 reads (3%) | catalogued as rs148392240; ClinVar: likely benign; called by muse, mutect2
- DHX33 | c.1839C>A p.S613= | Silent (SNP) | VAF 23/194 reads (12%) | catalogued as COSV56579634; called by muse, mutect2, varscan2
- LUC7L2 | c.78A>G p.Q26= | Silent (SNP) | VAF 66/206 reads (32%) | catalogued as rs750600991, COSV99693193; called by muse, mutect2, varscan2
- MYO19 | c.1500C>T p.A500= | Silent (SNP) | VAF 31/228 reads (14%) | called by muse, mutect2, varscan2
- NELL2 | c.2343C>T p.R781= | Silent (SNP) | VAF 12/312 reads (4%) | catalogued as COSV100419920; called by muse, mutect2
- SERPINA13P | n.364C>G | RNA (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
